Somatic mutation profile of tumor specimen C3L-01257-01 (aliquot CPT0073520009) from CPTAC case C3L-01257, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 71.9 years (26,274 days).
Specimen C3L-01257-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb28d821-39c8-47e1-8930-ead4e1764cd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01257-71 (Blood Derived Normal), aliquot CPT0073580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c83e6dc-71f0-40b7-84c7-16d09132bdd5

The open-access MAF lists 668 somatic variants for this specimen: 454 protein-altering or splice-affecting, 123 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 281, Silent 123, Frame Shift Del 113, Intron 52, Nonsense Mutation 18, Frame Shift Ins 17, 5'UTR 12, 3'UTR 11, In Frame Del 9, RNA 9, Splice Region 7, Splice Site 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 177/533 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- BRCA2 | c.6574del p.M2192Wfs*14 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs1060502392; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CIC | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 112/334 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50590933, COSV99360194; called by muse, mutect2, varscan2
- EIF1AX | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 28/108 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV63309390, COSV63309515; called by muse, varscan2
- FGFR2 | c.1639A>G p.I547V | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1057519798, COSV60643206; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554927408, CM960654, COSV60640087, COSV60649627; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 90/182 reads (49%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NAA15 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1274633498, COSV56719543; ClinVar: pathogenic; called by muse, mutect2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 139/411 reads (34%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 149/472 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.5069T>C p.M1690T | Missense Mutation (SNP) | VAF 130/423 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1333985048; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 58/202 reads (29%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- AC018630.4 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs889055205; called by muse, mutect2, varscan2
- ACTL7A | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758729154, COSV61776227; called by muse, mutect2, varscan2
- ADAMTSL4 | c.963del p.T322Lfs*21 | Frame Shift Del (DEL) | VAF 38/200 reads (19%) | catalogued as rs748115277, COSV55000781; called by mutect2, varscan2
- ADGRL1 | c.658G>A p.D220N (on ENST00000340736 / NM_001008701.3; = p.D215N on NM_014921.5) | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100529236; called by muse, mutect2, varscan2
- ADGRL1 | c.482G>A p.G161D (on ENST00000340736 / NM_001008701.3; = p.G156D on NM_014921.5) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1483967349; called by muse, mutect2, varscan2
- ADRA1B | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as rs1238651925; called by muse, mutect2, varscan2
- AGFG1 | c.1319C>G p.A440G | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59514012; called by muse, varscan2
- AGXT | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs147497484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1L1 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs368202745, COSV99856718; called by muse, mutect2, varscan2
- ALPK1 | c.2225_2227del p.E742del | In Frame Del (DEL) | VAF 32/126 reads (25%) | catalogued as rs760463685; called by pindel, varscan2
- AMY2B | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs529999526; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 49/180 reads (27%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ARHGEF26 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs757436159; called by muse, mutect2, varscan2
- ASIC1 | c.529del p.E177Rfs*31 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as COSV57319909; called by mutect2, varscan2
- ASXL3 | c.6301G>A p.V2101I | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.315); catalogued as COSV52462118; called by muse, mutect2, varscan2
- ATG9B | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs760200978; called by muse, mutect2, varscan2
- ATP9A | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as COSV100125782; called by muse, mutect2
- CAB39L | c.890del p.N297Ifs*9 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | catalogued as COSV61716482; called by mutect2, pindel, varscan2
- CABLES1 | c.157del p.R53Gfs*80 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs1568038325; called by mutect2, varscan2
- CACTIN | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs200387014, COSV50273896; called by muse, mutect2, varscan2
- CAPN2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139659399; called by muse, mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs768812342; called by mutect2, varscan2
- CBX4 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 194/313 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs1283056126; called by muse, mutect2, varscan2
- CCDC166 | c.961del p.R321Gfs*41 | Frame Shift Del (DEL) | VAF 52/174 reads (30%) | catalogued as COSV72638932; called by mutect2, varscan2
- CCDC166 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as rs1554616768; called by muse, mutect2, varscan2
- CCDC24 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV58843941; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 35/127 reads (28%) | catalogued as rs779465056; called by mutect2, pindel, varscan2
- CERT1 | c.845G>A p.G282D (on ENST00000405807 / NM_001130105.1; = p.G154D on NM_005713.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs1319173960; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs751492244; called by mutect2, varscan2
- COL12A1 | c.6682C>T p.R2228W | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759202641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO1A | c.637_639del p.X213_splice | Splice Site (DEL) | VAF 154/507 reads (30%) | catalogued as rs868444674; called by mutect2, pindel, varscan2
- CPED1 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs758347698; called by muse, mutect2, varscan2
- CPNE7 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759360639, COSV99081819; called by muse, mutect2, varscan2
- CR2 | c.624dup p.T209Hfs*3 | Frame Shift Ins (INS) | VAF 98/356 reads (28%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACD | c.3493C>T p.R1165C | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747217847; called by muse, mutect2, varscan2
- CREB3L4 | c.715_717del p.K239del | In Frame Del (DEL) | VAF 60/286 reads (21%) | catalogued as rs749320152; called by pindel, varscan2
- CRMP1 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs768538875, COSV61478733; called by muse, mutect2, varscan2
- CROCC | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 100/533 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs754708972, COSV65010714; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CYP11B2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 157/518 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750090886, COSV59994448; called by muse, mutect2, varscan2
- CYSRT1 | c.485C>A p.P162H (on ENST00000409414; = p.P122H on NM_199001.5) | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs376612265; called by muse, mutect2, varscan2
- DCAF15 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339981092; called by muse, mutect2, varscan2
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | catalogued as rs755611865; called by mutect2, pindel, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DLGAP2 | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.99); catalogued as rs780086050; called by muse, mutect2, varscan2
- DNAH17 | c.7532C>T p.P2511L | Missense Mutation (SNP) | VAF 89/145 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257968419; called by muse, mutect2, varscan2
- DNASE1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 128/465 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752868705, COSV55912708; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- ENOX2 | c.1024G>A p.A342T (on ENST00000338144 / NM_001382520.1; = p.A313T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs749365956, COSV57652229, COSV57655915; called by muse, mutect2, varscan2
- ETAA1 | c.2153T>C p.M718T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1202036330; called by muse, mutect2, varscan2
- FANCM | c.4697T>C p.M1566T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV57499491; called by muse, mutect2, varscan2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | catalogued as rs1461432773; called by mutect2, varscan2
- FBRSL1 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs1233605862; called by muse, mutect2, varscan2
- FBXL12 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746588749, COSV56113581; called by muse, mutect2, varscan2
- FOXRED1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416090738, COSV55005144; called by muse, mutect2, varscan2
- G3BP2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 117/423 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV62976140; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 54/185 reads (29%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GCN1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs540952471, COSV100324833, COSV56114320; called by muse, mutect2, varscan2
- GEMIN5 | c.2176del p.S726Vfs*24 | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | catalogued as COSV53564949; called by mutect2, pindel, varscan2
- GLT1D1 | c.647C>T p.A216V (on ENST00000442111 / NM_001366889.1; = p.A136V on NM_144669.3) | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV55888821; called by muse, mutect2, varscan2
- GPR35 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.398); catalogued as rs368384952; called by muse, mutect2, varscan2
- GPRASP1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753112472, COSV64355287; called by mutect2, varscan2
- GPSM1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 11/342 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs782695513; called by muse, mutect2
- GRM7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761983302, COSV63151566; called by muse, mutect2, varscan2
- GTPBP2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769628380, COSV61076643; called by muse, mutect2, varscan2
- GUCY1A2 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768283586, COSV56481474, COSV56494023, COSV56503287; called by muse, mutect2, varscan2
- HDHD5 | c.678del p.Y227Tfs*7 (on ENST00000336737 / NM_033070.3; = p.Y197Tfs*7 on NM_017829.5) | Frame Shift Del (DEL) | VAF 42/141 reads (30%) | catalogued as rs760251393; called by mutect2, pindel, varscan2
- HELZ2 | c.5375G>A p.R1792Q (on ENST00000467148 / NM_001037335.2; = p.R1223Q on NM_033405.3) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs979193169; called by muse, mutect2
- HIBCH | c.793A>G p.M265V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs377127635; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV99670288; called by mutect2, pindel
- HTT | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs369875192; called by muse, mutect2, varscan2
- ICE1 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs752071785, COSV56823531; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs760925109; called by mutect2, varscan2
- IPCEF1 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1262889668, COSV99036473; called by muse, mutect2
- IQSEC1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs1201035554; called by muse, mutect2, varscan2
- IQSEC3 | c.1376C>T p.A459V (on ENST00000538872 / NM_001170738.2; = p.A156V on NM_015232.1) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs572367293, COSV58288542; called by muse, mutect2, varscan2
- IRS2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1413050017; called by muse, mutect2, varscan2
- JUP | c.193del p.V65Cfs*95 | Frame Shift Del (DEL) | VAF 105/411 reads (26%) | catalogued as COSV100159598, COSV60277953; called by mutect2, pindel, varscan2
- KANK3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 159/470 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs959229907; called by muse, mutect2, varscan2
- KCND2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 82/434 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs757409386, COSV58592426; called by muse, mutect2, varscan2
- KCNK9 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57286400; called by muse, mutect2
- KCNS2 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs751437110, COSV54640014; called by muse, mutect2, varscan2
- KHDC3L | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1488094962, COSV64863982, COSV99059405; called by muse, mutect2, varscan2
- KIAA1522 | c.746G>A p.R249Q (on ENST00000373480 / NM_001198972.2; = p.R308Q on NM_020888.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as rs775914331; called by muse, mutect2, varscan2
- KIAA2026 | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1186736808, COSV67353454; called by muse, mutect2, varscan2
- KIF19 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 151/258 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs199824477; called by muse, mutect2, varscan2
- KMT2B | c.4235G>T p.G1412V | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55872982; called by muse, varscan2
- KMT2B | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs762074423, COSV99033141; called by muse, varscan2
- KRT12 | c.1095+8C>T | Splice Region (SNP) | VAF 153/555 reads (28%) | catalogued as rs771352143; called by muse, mutect2, varscan2
- KRT75 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 155/445 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs370991901, COSV99359189; called by muse, mutect2, varscan2
- KRTAP19-6 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs191391687; called by muse, mutect2, varscan2
- LCT | c.4403C>A p.A1468E | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV51550861, COSV51552680; called by muse, mutect2, varscan2
- LDHB | c.421+6_421+8del | Splice Region (DEL) | VAF 20/89 reads (22%) | catalogued as rs770406202; called by pindel, varscan2
- LDLRAD1 | c.364del p.H122Tfs*33 | Frame Shift Del (DEL) | VAF 50/209 reads (24%) | catalogued as rs775788835; called by mutect2, pindel, varscan2
- LETM1 | c.1831del p.R611Gfs*5 | Frame Shift Del (DEL) | VAF 86/256 reads (34%) | catalogued as COSV100245158; called by mutect2, varscan2
- LIG3 | c.994C>G p.R332G | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV52012022; called by muse, mutect2, varscan2
- LIMS2 | c.307G>A p.E103K (on ENST00000355119 / NM_001161403.3; = p.E127K on NM_017980.4) | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV99760427; called by muse, mutect2, varscan2
- LRRC15 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750347638, COSV61651611; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | catalogued as rs753028254; called by mutect2, pindel, varscan2
- MAGED1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.071); catalogued as rs1557364172, COSV100431700; called by muse, mutect2, varscan2
- MAN1B1 | c.1255-1G>T p.X419_splice | Splice Site (SNP) | VAF 128/463 reads (28%) | catalogued as COSV100857272; called by muse, mutect2, varscan2
- MAPK4 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1392499285; called by muse, mutect2, varscan2
- MAST4 | c.1618A>G p.S540G (on ENST00000403625 / NM_001164664.2; = p.S351G on NM_015183.3) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs762612899; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD1 | c.1072G>A p.D358N (on ENST00000269468 / NM_001323950.1; = p.D335N on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54006984; called by muse, mutect2, varscan2
- MBD1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 102/304 reads (34%) | catalogued as COSV53999446; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 38/81 reads (47%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MICAL3 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.174); catalogued as rs1451360941, COSV99261101; called by muse, mutect2
- MRPL19 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs190537239; called by muse, mutect2, varscan2
- MTMR4 | c.60del p.K21Rfs*3 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | catalogued as rs750261859; called by mutect2, pindel, varscan2
- MUC5B | c.10667G>A p.S3556N | Missense Mutation (SNP) | VAF 128/565 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs780055926; called by muse, mutect2, varscan2
- MYH15 | c.5691G>A p.A1897= | Splice Region (SNP) | VAF 37/126 reads (29%) | catalogued as rs201882141, COSV99842683; called by muse, mutect2, varscan2
- MYO1A | c.2110A>G p.I704V | Missense Mutation (SNP) | VAF 137/420 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs1220464536; called by muse, mutect2, varscan2
- MYOM2 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555367835, COSV50719722; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as rs763929397; called by mutect2, varscan2
- NELL2 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs368968650; called by muse, mutect2, varscan2
- NFATC1 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53694378; called by muse, mutect2, varscan2
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | catalogued as rs145147241; called by mutect2, varscan2
- NOS3 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 78/396 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as rs765572803, COSV52486913; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NUCKS1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV65652919; called by muse, mutect2, varscan2
- NUMA1 | c.6257G>A p.R2086H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs574732890, COSV99474525; called by muse, mutect2, varscan2
- NXPE3 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as COSV56291853; called by muse, mutect2, varscan2
- OPCML | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1205739187; called by muse, mutect2, varscan2
- ORC3 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs550694781; called by muse, mutect2, varscan2
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | catalogued as rs1217359611; called by mutect2, pindel, varscan2
- PANX3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267602763, COSV99421084; called by muse, mutect2, varscan2
- PAXIP1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as rs760584538, COSV101249767, COSV68185672; called by muse, mutect2, varscan2
- PCK1 | c.1658C>T p.T553M | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762446688, COSV60126174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCNX3 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs756949255, COSV100856341; called by muse, mutect2, varscan2
- PCOLCE2 | c.813del p.K271Nfs*16 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs752255624; called by mutect2, varscan2
- PDK3 | c.521del p.G174Vfs*11 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | catalogued as COSV100998192; called by mutect2, pindel, varscan2
- PER2 | c.3113G>A p.R1038H | Missense Mutation (SNP) | VAF 135/512 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs780467105, COSV99612110; called by muse, mutect2, varscan2
- PGM2 | c.344del p.G115Vfs*27 | Frame Shift Del (DEL) | VAF 38/165 reads (23%) | catalogued as rs757233436; called by mutect2, pindel, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as rs925772654; called by mutect2, pindel
- PIGU | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1195827620; called by muse, mutect2, varscan2
- PLCH2 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs896994138; called by muse, mutect2, varscan2
- PLEC | c.5840C>T p.A1947V (on ENST00000322810 / NM_201380.4; = p.A1837V on NM_000445.5) | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs781987856, COSV100516277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.2351G>A p.R784H (on ENST00000322810 / NM_201380.4; = p.R674H on NM_000445.5) | Missense Mutation (SNP) | VAF 112/323 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782103383, COSV59621064; called by muse, mutect2, varscan2
- PLXNA1 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs142147514, COSV52530883; called by muse, mutect2, varscan2
- POP4 | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as rs758409161; called by muse, mutect2, varscan2
- POU2F2 | c.1285del p.L429Sfs*34 (on ENST00000526816 / NM_001207025.3; = p.L413Sfs*34 on NM_002698.5) | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs746693584, COSV60766181; called by mutect2, varscan2
- PROKR2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs573392596, COSV54087847; called by muse, mutect2, varscan2
- PRR14L | c.5825C>T p.T1942M | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs535691979; called by muse, mutect2, varscan2
- PRR36 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); catalogued as rs866457453; called by muse, mutect2
- PTER | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200727239, COSV100126774, COSV54346811; called by muse, mutect2, varscan2
- PTPRT | c.2584del p.R862Gfs*20 | Frame Shift Del (DEL) | VAF 73/238 reads (31%) | catalogued as COSV61978956; called by mutect2, pindel, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 42/172 reads (24%) | catalogued as rs770990761; called by mutect2, varscan2
- RBBP8 | c.1900T>C p.C634R | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs372240272; called by muse, mutect2, varscan2
- REV3L | c.5654dup p.S1886Kfs*2 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | catalogued as rs761303551; called by mutect2, varscan2
- RNF113B | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1411230392, COSV57434679; called by muse, mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 50/169 reads (30%) | catalogued as rs745561139; called by mutect2, pindel, varscan2
- RPS6KA6 | c.327dup p.A110Sfs*36 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | catalogued as rs756096568; called by mutect2, varscan2
- RSPH14 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs767247482; called by muse, mutect2, varscan2
- RUNX1 | c.706C>T p.P236S (on ENST00000344691 / NM_001001890.3; = p.P263S on NM_001754.5) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as rs370315332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.7150G>A p.E2384K | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs762896797, COSV66543934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD10 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV53876704; called by muse, mutect2, varscan2
- SBNO2 | c.3791del p.P1264Rfs*89 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs1447461489, COSV62321793; called by mutect2, pindel, varscan2
- SCARA5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs763502328; called by muse, mutect2, varscan2
- SCN2A | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750049844, COSV51834008; called by muse, mutect2, varscan2
- SCUBE3 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51460069; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as rs750651342; called by mutect2, varscan2
- SETD1B | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as rs1024820256, COSV99930579; called by muse, mutect2, varscan2
- SGK3 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs760837872, COSV61894928; called by muse, mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as COSV53462966; called by mutect2, pindel, varscan2
- SIGLEC1 | c.3629G>A p.R1210H | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs749207473; called by muse, mutect2, varscan2
- SLC25A47 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762332905, COSV59925016, COSV59927290; called by muse, mutect2, varscan2
- SLC38A10 | c.2974dup p.D992Gfs*84 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | catalogued as rs762295813; called by mutect2, varscan2
- SLC39A3 | c.138_139dup p.C47Sfs*22 | Frame Shift Ins (INS) | VAF 124/497 reads (25%) | catalogued as rs1465649714; called by mutect2, varscan2
- SLC3A2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as rs1477148018, COSV58604218; called by muse, mutect2, varscan2
- SLC4A5 | c.3267del p.A1091Pfs*17 | Frame Shift Del (DEL) | VAF 60/162 reads (37%) | catalogued as rs1558864722; called by mutect2, pindel, varscan2
- SLC7A8 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs1470081163; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCA4 | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 168/626 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs145476154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCC2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV57216651; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs760667210; called by mutect2, varscan2
- SNX18 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs1390491895, COSV57990886; called by muse, mutect2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTA1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs772560248, COSV63751978; called by muse, mutect2, varscan2
- SRCAP | c.9413G>A p.R3138H | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs768891825, COSV52668601; called by muse, mutect2, varscan2
- STAG3 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748067739; called by muse, mutect2, varscan2
- STARD9 | c.5328del p.R1777Gfs*18 | Frame Shift Del (DEL) | VAF 38/155 reads (25%) | catalogued as COSV51902250; called by mutect2, pindel, varscan2
- SYNPO2L | c.1961C>T p.S654L (on ENST00000394810 / NM_001114133.3; = p.S430L on NM_024875.5) | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100866491; called by muse, mutect2, varscan2
- TAF15 | c.1777T>C p.*593Rext*1 (on ENST00000605844 / NM_139215.3; = p.*590Rext*1 on NM_003487.4) | Nonstop Mutation (SNP) | VAF 57/243 reads (23%) | catalogued as rs1315157032; called by muse, mutect2, varscan2
- TBX5 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV59861649; called by muse, mutect2, varscan2
- TDRD6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201364675; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 62/261 reads (24%) | catalogued as rs782753958; called by mutect2, varscan2
- TGM2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs781011976, COSV63931355; called by muse, mutect2, varscan2
- TIMM22 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1287800075; called by muse, mutect2
- TM4SF1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 70/302 reads (23%) | catalogued as rs768672228; called by muse, mutect2, varscan2
- TMEM35A | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 55/169 reads (33%) | catalogued as COSV54507248; called by muse, mutect2, varscan2
- TMPRSS6 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1237361829; called by muse, mutect2, varscan2
- TP73 | c.1004del p.P335Lfs*10 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | catalogued as COSV104414957; called by mutect2, pindel, varscan2
- TREM2 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.212); catalogued as rs751357650; called by muse, mutect2, varscan2
- TRIM59 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs552078520; called by muse, mutect2, varscan2
- TRPM4 | c.178del p.V60Cfs*218 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as COSV53260046; called by mutect2, pindel, varscan2
- TTC27 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 118/443 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1170478700; called by muse, mutect2, varscan2
- TUFM | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 124/442 reads (28%) | catalogued as rs1231538511, COSV57948859; called by muse, mutect2, varscan2
- TULP4 | c.3504C>G p.F1168L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100893517; called by muse, mutect2, varscan2
- TUT4 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.033); catalogued as rs756328159; called by muse, varscan2
- USP15 | c.1030G>A p.E344K (on ENST00000280377 / NM_001351159.2; = p.E315K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1170099248, COSV99740401; called by muse, mutect2, varscan2
- USP2 | c.238del p.L80Cfs*2 | Frame Shift Del (DEL) | VAF 54/188 reads (29%) | catalogued as rs753538451; called by mutect2, pindel, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as rs761345427; called by mutect2, pindel
- USP9X | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs1300933321; called by muse, mutect2, varscan2
- WDR1 | c.1398C>T p.D466= (on ENST00000382452; = p.D326= on NM_005112.5) | Splice Region (SNP) | VAF 17/72 reads (24%) | catalogued as rs201075123; called by muse, mutect2, varscan2
- WIPF3 | c.1082_1084del p.K361del | In Frame Del (DEL) | VAF 54/182 reads (30%) | catalogued as rs747804139; called by pindel, varscan2
- WNK3 | c.3938G>A p.R1313Q | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs368509222; called by muse, mutect2, varscan2
- WWC2 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775523719, COSV66716455; called by muse, mutect2, varscan2
- XIRP1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.13); catalogued as rs1415926046; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs1403895317; called by mutect2, pindel
- YAP1 | c.147del p.A50Pfs*24 | Frame Shift Del (DEL) | VAF 74/262 reads (28%) | catalogued as rs1555075353; called by mutect2, pindel, varscan2
- ZC3H12C | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs768457807, COSV53710892; called by muse, mutect2, varscan2
- ZMAT2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99218162; called by muse, mutect2, varscan2
- ZNF148 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62302081; called by muse, mutect2, varscan2
- ZNF358 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs759381942, COSV51183159; called by muse, mutect2, varscan2
- ZNF628 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1348721418, COSV52700539; called by muse, mutect2, varscan2
- ZNF70 | c.242del p.P81Qfs*26 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | catalogued as rs775749922; called by mutect2, varscan2
- ZNF835 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV73379734; called by muse, mutect2, varscan2
- ABCD3 | c.1355_1357dup p.G452dup | In Frame Ins (INS) | VAF 78/223 reads (35%) | called by mutect2, pindel, varscan2
- ABCG4 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ABHD11 | c.50_94del p.W17_A32delinsS | In Frame Del (DEL) | VAF 114/325 reads (35%) | called by mutect2, pindel
- ADAMTS15 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- AKAP13 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AKR1C8P | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF9 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ARID1A | c.6134_6135del p.K2045Sfs*53 | Frame Shift Del (DEL) | VAF 75/257 reads (29%) | called by mutect2, pindel, varscan2
- ASPSCR1 | c.407del p.P136Qfs*10 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | called by mutect2, pindel, varscan2
- ATM | c.1947del p.E650Nfs*14 | Frame Shift Del (DEL) | VAF 53/165 reads (32%) | called by mutect2, pindel, varscan2
- ATM | c.4908G>T p.Q1636H | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ATN1 | c.2622del p.Y875Tfs*78 | Frame Shift Del (DEL) | VAF 54/229 reads (24%) | called by mutect2, pindel, varscan2
- B3GLCT | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BAHCC1 | c.2502del p.H835Tfs*139 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- BARX1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- C21orf58 | c.540del p.T181Rfs*41 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel
- C2CD2L | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- C3orf20 | c.1721del p.K574Rfs*11 | Frame Shift Del (DEL) | VAF 49/158 reads (31%) | called by mutect2, pindel, varscan2
- CATSPER1 | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CBX4 | c.1593C>G p.S531R | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC18 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- CCDC74A | c.975dup p.K326Qfs*75 | Frame Shift Ins (INS) | VAF 39/181 reads (22%) | called by mutect2, varscan2
- CCNB3 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- CCR3 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD79B | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 150/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CEP295 | c.6395_6397del p.R2132del | In Frame Del (DEL) | VAF 44/148 reads (30%) | called by pindel, varscan2
- CFAP74 | c.3236del p.P1079Qfs*34 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- CHD1 | c.5018G>A p.S1673N | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CHD1 | c.3479A>C p.K1160T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CLEC4G | c.29del p.G10Afs*38 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | called by mutect2, pindel, varscan2
- COA1 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- COL20A1 | c.1204del p.R402Gfs*7 | Frame Shift Del (DEL) | VAF 55/158 reads (35%) | called by mutect2, pindel, varscan2
- COL5A2 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- COL6A6 | c.3447del p.T1151Lfs*6 | Frame Shift Del (DEL) | VAF 54/226 reads (24%) | called by mutect2, pindel, varscan2
- COX17 | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 73/222 reads (33%) | called by muse, mutect2, varscan2
- CPED1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CPSF1 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, varscan2
- CROCC2 | c.4603G>T p.G1535W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYFIP2 | c.3353A>G p.E1118G (on ENST00000616178 / NM_001291722.2; = p.E1093G on NM_014376.4) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DAB2 | c.330+4A>G | Splice Region (SNP) | VAF 63/229 reads (28%) | called by muse, mutect2, varscan2
- DGCR6L | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- DLEC1 | c.5066dup p.N1690Kfs*28 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- DLG5 | c.4188+2T>C p.X1396_splice | Splice Site (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2
- DMGDH | c.505del p.I169Ffs*10 | Frame Shift Del (DEL) | VAF 79/218 reads (36%) | called by mutect2, pindel, varscan2
- DNAH10 | c.10984G>A p.A3662T (on ENST00000409039; = p.A3601T on NM_207437.3) | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.169); called by muse, mutect2
- DNAH3 | c.11866A>G p.I3956V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DNAH7 | c.11098C>T p.P3700S | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DRD5 | c.41A>G p.Q14R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- DYNC1H1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2
- EGFR | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPAS1 | c.1410dup p.S471Qfs*14 | Frame Shift Ins (INS) | VAF 74/253 reads (29%) | called by pindel, varscan2
- EPHA6 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ERI1 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ETNPPL | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ETV7 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- EXO5 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- FAIM2 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FAM110A | c.740del p.G247Afs*8 | Frame Shift Del (DEL) | VAF 54/163 reads (33%) | called by mutect2, pindel, varscan2
- FAM149A | c.122del p.G41Afs*163 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | called by mutect2, pindel, varscan2
- FAM50A | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- FAM98A | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- FANCI | c.3578del p.N1193Ifs*6 (on ENST00000310775 / NM_001376911.1; = p.N1133Ifs*6 on NM_018193.3) | Frame Shift Del (DEL) | VAF 68/313 reads (22%) | called by mutect2, varscan2
- FBN2 | c.6254del p.P2085Lfs*164 | Frame Shift Del (DEL) | VAF 46/208 reads (22%) | called by mutect2, pindel, varscan2
- FBXO46 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLT1 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 97/335 reads (29%) | called by muse, mutect2, varscan2
- FOXD4L3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by mutect2, varscan2
- FOXD4L6 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by mutect2, varscan2
- FRMD4A | c.*2G>T | Splice Region (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- FUBP1 | c.901del p.I301Yfs*22 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | called by mutect2, pindel, varscan2
- GAB4 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GCM2 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GDF1 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 121/422 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEN1 | c.1579A>G p.N527D | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFAP | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGT5 | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GOLGB1 | c.4860G>C p.Q1620H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPRASP1 | c.1859G>T p.R620I | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2D | c.1208G>C p.S403T | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HDAC6 | c.3098del p.P1033Qfs*17 | Frame Shift Del (DEL) | VAF 66/293 reads (23%) | called by mutect2, pindel, varscan2
- HELZ2 | c.7855del p.L2619Sfs*? (on ENST00000467148 / NM_001037335.2; = p.L2050Sfs*139 on NM_033405.3) | Frame Shift Del (DEL) | VAF 41/124 reads (33%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.162T>G p.S54R | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HOMER2 | c.998T>C p.L333P (on ENST00000304231 / NM_199330.3; = p.L322P on NM_004839.4) | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HSD17B13 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HSFX2 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.189); called by mutect2, varscan2
- HTATSF1 | c.1503del p.E502Sfs*91 | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | called by mutect2, pindel, varscan2
- ILKAP | c.851T>G p.L284W | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, varscan2
- INTS8 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- IPO13 | c.1028G>A p.C343Y | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IRAK1 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- IRGQ | c.1856del p.P619Lfs*17 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ISG20 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 77/160 reads (48%) | called by mutect2, varscan2
- JPH2 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 17/518 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- KANSL1 | c.2087A>T p.K696I | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KCNH4 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KCNIP2 | c.170C>T p.T57I (on ENST00000356640 / NM_173191.3; = p.A72V on NM_014591.5) | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNU1 | c.162dup p.W55Mfs*21 | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- KCTD7 | c.692G>A p.C231Y (on ENST00000275532; = p.L244= on NM_153033.5) | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KLHDC3 | c.155-2A>G p.X52_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- KMT2A | c.173del p.P58Rfs*92 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel
- KMT2B | c.7161T>C p.G2387= | Splice Region (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2
- KPNA6 | c.516del p.F172Lfs*2 | Frame Shift Del (DEL) | VAF 51/168 reads (30%) | called by mutect2, pindel, varscan2
- LAMA2 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- LAMB2 | c.5006C>A p.A1669D | Missense Mutation (SNP) | VAF 152/555 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LAS1L | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- LBH | c.221A>C p.E74A | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LDB3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 127/477 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LINGO2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LINGO4 | c.222del p.L75Sfs*9 | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- LMO3 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LONP1 | c.1762_1764del p.L588del | In Frame Del (DEL) | VAF 40/113 reads (35%) | called by mutect2, pindel, varscan2
- MAGEB1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MARCHF8 | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MED10 | c.388del p.E130Rfs*14 | Frame Shift Del (DEL) | VAF 44/227 reads (19%) | called by mutect2, pindel, varscan2
- MEX3C | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAT4D | c.926del p.L309* | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, varscan2
- MISP3 | c.370del p.H124Tfs*44 | Frame Shift Del (DEL) | VAF 158/506 reads (31%) | called by mutect2, pindel, varscan2
- MTA3 | c.1778C>T p.S593L (on ENST00000405094 / NM_001330442.2; = p.S536L on NM_001282755.1) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MTSS1 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCAN | c.3407A>G p.N1136S | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NHSL2 | c.952G>A p.A318T (on ENST00000510661; = p.A684T on NM_001013627.2) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKX1-1 | c.803del p.G268Afs*73 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- NOC2L | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- NUAK1 | c.139_141del p.H47del | In Frame Del (DEL) | VAF 66/272 reads (24%) | called by pindel, varscan2
- NUP210L | c.602dup p.I202Nfs*5 | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- NUTM2B | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 51/375 reads (14%) | called by muse, mutect2, varscan2
- OLFM3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OMD | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- OR8D4 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OSBP2 | c.1887del p.S630Qfs*34 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, varscan2
- OTOGL | c.602A>C p.N201T (on ENST00000547103; = p.N192T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OXTR | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 70/232 reads (30%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 142/488 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHGB2 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PCLO | c.14803A>G p.N4935D | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PCM1 | c.2234_2235del p.E745Afs*13 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by pindel, varscan2
- PDS5B | c.3585del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- PIK3C2A | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1732_1733del p.D578Pfs*23 (on ENST00000521381 / NM_181523.3; = p.D308Pfs*23 on NM_181504.4) | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by pindel, varscan2
- PKN3 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PLCH1 | c.1949A>G p.K650R (on ENST00000340059 / NM_001130960.2; = p.K662R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PLEKHM3 | c.1340G>A p.W447* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4315C>T p.L1439F | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- POU4F2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); called by muse, varscan2
- PPP1R9A | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM2 | c.1554del p.G519Efs*48 | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | called by mutect2, pindel, varscan2
- PROSER1 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PRPF6 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTEN | c.88_95del p.P30Yfs*11 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- PTPN21 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN3 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | called by mutect2, pindel, varscan2
- RELN | c.9186del p.F3062Lfs*19 | Frame Shift Del (DEL) | VAF 95/347 reads (27%) | called by mutect2, pindel, varscan2
- RGS22 | c.2742del p.K914Nfs*18 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- RNF34 | c.662_663del p.T221Rfs*3 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by pindel, varscan2
- ROBO1 | c.2265dup p.N756* | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, varscan2
- RPAP2 | c.1784del p.N595Mfs*7 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- RTP5 | c.572dup p.G192Wfs*23 | Frame Shift Ins (INS) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- RTTN | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SAMD1 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAPCD1 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCLY | c.326A>T p.E109V (on ENST00000651534; = p.E101V on NM_016510.7) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCML4 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN2A | c.1508del p.N503Tfs*30 | Frame Shift Del (DEL) | VAF 68/354 reads (19%) | called by mutect2, pindel, varscan2
- SIAE | c.722+2T>C p.X241_splice | Splice Site (SNP) | VAF 70/267 reads (26%) | called by muse, mutect2, varscan2
- SIGMAR1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SLC1A1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 179/524 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A25 | c.486+1G>A p.X162_splice | Splice Site (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- SLC25A25 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLC25A6 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 127/462 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SLC2A5 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC38A7 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLX4IP | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SNPH | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPATA5 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, mutect2
- SPINK5 | c.1022dup p.N341Kfs*2 | Frame Shift Ins (INS) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.96del p.D33Tfs*23 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- STAB1 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- STK39 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SULT2A1 | c.17T>C p.L6S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SUOX | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 65/210 reads (31%) | called by mutect2, pindel, varscan2
- SYCP2L | c.2145del p.K715Nfs*27 | Frame Shift Del (DEL) | VAF 36/167 reads (22%) | called by mutect2, pindel, varscan2
- SYNDIG1 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TBC1D10C | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.364del p.Q122Rfs*62 | Frame Shift Del (DEL) | VAF 73/204 reads (36%) | called by mutect2, pindel, varscan2
- TEX9 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- THADA | c.2887G>T p.V963L | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TIE1 | c.1341del p.V448Cfs*9 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- TLE1 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TMEM161B | c.1343del p.N448Ifs*15 | Frame Shift Del (DEL) | VAF 74/202 reads (37%) | called by mutect2, pindel, varscan2
- TMEM209 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 83/416 reads (20%) | called by muse, mutect2, varscan2
- TMEM45A | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM80 | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- TNN | c.2705C>T p.T902I | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TP53 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 190/591 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPTE | c.1538del p.N513Mfs*29 (on ENST00000618007 / NM_199261.4; = p.N495Mfs*29 on NM_199259.4) | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by mutect2, pindel, varscan2
- TRIM24 | c.2015-1G>T p.X672_splice (on ENST00000343526 / NM_015905.3; = p.X638_splice on NM_003852.4) | Splice Site (SNP) | VAF 63/239 reads (26%) | called by muse, mutect2, varscan2
- TTC25 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTI2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.9107C>A p.A3036D (on ENST00000591111; = p.A2990D on NM_003319.4) | Missense Mutation (SNP) | VAF 60/190 reads (32%) | PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- UBE2O | c.3052del p.H1018Tfs*12 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ULK2 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.6065C>T p.A2022V | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USH2A | c.3956C>T p.P1319L | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- USP38 | c.238_240del p.F80del | In Frame Del (DEL) | VAF 72/242 reads (30%) | called by pindel, varscan2
- VPS13A | c.8653del p.Y2885Mfs*20 | Frame Shift Del (DEL) | VAF 70/242 reads (29%) | called by mutect2, pindel, varscan2
- VPS50 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA8 | c.1147_1149del p.M383del | In Frame Del (DEL) | VAF 52/156 reads (33%) | called by pindel, varscan2
- WAC | c.61del p.D21Tfs*171 | Frame Shift Del (DEL) | VAF 44/145 reads (30%) | called by mutect2, pindel, varscan2
- WDFY3 | c.5420G>A p.C1807Y | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WLS | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WNK1 | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ZFHX3 | c.10511T>C p.V3504A | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ZFHX3 | c.214_215insG p.S72Cfs*47 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | called by mutect2, pindel*, varscan2
- ZFHX4 | c.4326del p.K1442Nfs*10 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | called by mutect2, pindel, varscan2
- ZFYVE16 | c.4505A>G p.H1502R | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, varscan2
- ZFYVE27 | c.759del p.K254Rfs*4 | Frame Shift Del (DEL) | VAF 102/352 reads (29%) | called by mutect2, pindel, varscan2
- ZNF518A | c.2014dup p.T672Nfs*8 | Frame Shift Ins (INS) | VAF 39/111 reads (35%) | called by mutect2, pindel, varscan2
- ZSCAN12 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ACAN | c.954C>T p.C318= | Silent (SNP) | VAF 69/218 reads (32%) | catalogued as rs1458616144, COSV100719210, COSV61371931; called by muse, mutect2, varscan2
- ADAM21 | c.606C>T p.D202= | Silent (SNP) | VAF 51/178 reads (29%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3084C>T p.S1028= (on ENST00000370717 / NM_001366005.1; = p.S1015= on NM_012302.4) | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- AGAP3 | c.1494C>T p.S498= (on ENST00000622464; = p.S534= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/290 reads (18%) | catalogued as rs554318518, COSV68244738; called by muse, mutect2, varscan2
- AGAP3 | c.2448C>T p.D816= (on ENST00000622464; = p.D852= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/332 reads (27%) | catalogued as rs201938549, COSV52547687; called by muse, mutect2, varscan2
- AHNAK | c.3639G>A p.V1213= | Silent (SNP) | VAF 69/259 reads (27%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.1029T>C p.H343= | Silent (SNP) | VAF 70/256 reads (27%) | called by muse, mutect2, varscan2
- ANAPC2 | c.1500C>T p.D500= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as rs777911287; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5022G>A p.K1674= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- ARPP21 | c.1308A>G p.S436= | Silent (SNP) | VAF 74/282 reads (26%) | catalogued as rs766989322; called by muse, mutect2, varscan2
- ARRDC2 | c.291G>A p.T97= | Silent (SNP) | VAF 54/239 reads (23%) | catalogued as COSV55843507; called by muse, mutect2, varscan2
- ATP9B | c.1686C>T p.A562= | Silent (SNP) | VAF 134/525 reads (26%) | catalogued as rs753635074; called by muse, mutect2, varscan2
- BCL9L | c.3972C>T p.F1324= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as rs780320678, COSV52682900, COSV52684788; called by muse, mutect2, varscan2
- C16orf71 | c.606G>A p.E202= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as rs758813266, COSV100173064; called by muse, mutect2, varscan2
- C16orf96 | c.3195C>T p.G1065= | Silent (SNP) | VAF 52/191 reads (27%) | catalogued as rs749292297, COSV101474697; called by muse, mutect2, varscan2
- C1orf127 | c.1443G>A p.T481= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs568588607; called by muse, mutect2, varscan2
- C8orf89 | c.426T>C p.I142= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, varscan2
- CACNG1 | c.558T>C p.C186= | Silent (SNP) | VAF 128/504 reads (25%) | called by muse, mutect2, varscan2
- CACNG3 | c.240C>T p.I80= | Silent (SNP) | VAF 45/210 reads (21%) | catalogued as rs765043632, COSV50066291; called by muse, mutect2, varscan2
- CCDC197 | c.234G>A p.T78= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as rs780657544, COSV58939254; called by muse, mutect2, varscan2
- CCDC86 | c.453G>A p.Q151= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as rs778749811; called by muse, mutect2, varscan2
- CCDC88C | c.3450C>T p.N1150= | Silent (SNP) | VAF 102/400 reads (26%) | catalogued as rs935425414, COSV66237607; called by muse, mutect2, varscan2
- CCT8L2 | c.627C>T p.P209= | Silent (SNP) | VAF 50/183 reads (27%) | catalogued as rs530849622, COSV63461742, COSV63464309; called by muse, mutect2, varscan2
- CD6 | c.1338G>A p.P446= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs201598086; called by muse, mutect2, varscan2
- CDCP1 | c.144C>T p.T48= | Silent (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- CECR2 | c.3471A>G p.P1157= (on ENST00000342247 / NM_001290047.2; = p.P973= on NM_001290046.1) | Silent (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- CELF5 | c.114C>T p.G38= | Silent (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- CES1 | c.960C>T p.G320= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as COSV62086120; called by muse, mutect2, varscan2
- CPSF7 | c.1005C>T p.A335= (on ENST00000394888 / NM_001136040.4; = p.A378= on NM_024811.4) | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs149166727; called by muse, mutect2, varscan2
- CPZ | c.402C>T p.D134= (on ENST00000360986 / NM_001014447.3; = p.D123= on NM_003652.3) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs143569240; called by muse, mutect2, varscan2
- DDR2 | c.1413C>T p.Y471= | Silent (SNP) | VAF 97/367 reads (26%) | catalogued as rs745562320, COSV63374994; called by muse, mutect2, varscan2
- DDX1 | c.1257C>T p.S419= | Silent (SNP) | VAF 45/173 reads (26%) | catalogued as rs541970738, COSV51837983; called by muse, mutect2, varscan2
- DLEU7 | c.360G>A p.A120= | Silent (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- DLGAP2 | c.834C>T p.S278= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as rs758736390, COSV70100214; called by muse, mutect2, varscan2
- DNAH11 | c.6559C>T p.L2187= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- DSPP | c.2319C>T p.S773= | Silent (SNP) | VAF 162/606 reads (27%) | called by mutect2, varscan2
- EIF2D | c.1077G>A p.E359= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1553410839; called by muse, mutect2, varscan2
- ELFN1 | c.2169G>A p.P723= | Silent (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- FAM186B | c.1474C>T p.L492= | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- FBXO10 | c.2442C>T p.T814= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- FBXO48 | c.198T>C p.N66= | Silent (SNP) | VAF 65/204 reads (32%) | called by muse, mutect2, varscan2
- FILIP1L | c.891G>A p.T297= (on ENST00000354552 / NM_182909.3; = p.T57= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/213 reads (23%) | catalogued as rs373047332; called by muse, mutect2, varscan2
- GLI3 | c.2916A>G p.P972= | Silent (SNP) | VAF 179/611 reads (29%) | catalogued as rs748644965; called by muse, mutect2, varscan2
- GZF1 | c.1209C>T p.G403= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs752982321, COSV57636301; called by muse, mutect2, varscan2
- HPD | c.273C>T p.D91= | Silent (SNP) | VAF 159/529 reads (30%) | catalogued as rs777153098; called by muse, mutect2, varscan2
- IFNL3 | c.72C>T p.V24= | Silent (SNP) | VAF 62/233 reads (27%) | catalogued as rs200909158; called by muse, mutect2, varscan2
- IGFBP7 | c.646C>T p.L216= | Silent (SNP) | VAF 113/364 reads (31%) | called by muse, mutect2, varscan2
- IKZF1 | c.879C>T p.Y293= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as rs1449573722, COSV100498111; called by muse, mutect2, varscan2
- IL37 | c.324G>A p.P108= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs150018952, COSV54490836; called by muse, mutect2
- IMP4 | c.723C>T p.N241= | Silent (SNP) | VAF 74/273 reads (27%) | catalogued as rs775233576, COSV52092357; called by muse, mutect2, varscan2
- IQSEC1 | c.1461C>A p.S487= | Silent (SNP) | VAF 104/349 reads (30%) | catalogued as COSV56227565; called by muse, mutect2, varscan2
- IQSEC1 | c.1135C>T p.L379= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- IRX1 | c.840G>A p.S280= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as rs755817015; called by muse, mutect2, varscan2
- ITGA10 | c.2031T>C p.T677= | Silent (SNP) | VAF 122/412 reads (30%) | catalogued as rs113368107; called by muse, mutect2, varscan2
- JAG2 | c.1074C>T p.N358= | Silent (SNP) | VAF 117/459 reads (25%) | catalogued as rs373042386; called by muse, mutect2, varscan2
- KCNQ2 | c.2280C>T p.R760= (on ENST00000359125 / NM_172107.4; = p.R732= on NM_004518.6) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs753696924; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KCNQ3 | c.2313G>A p.S771= | Silent (SNP) | VAF 112/321 reads (35%) | catalogued as rs774793856; called by muse, mutect2, varscan2
- KDM1B | c.1914T>A p.I638= (on ENST00000449850; = p.I405= on NM_153042.4) | Silent (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- KIF11 | c.1269T>C p.I423= | Silent (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- KLHL40 | c.525C>T p.D175= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs775038339, COSV55132588; called by muse, mutect2, varscan2
- KNSTRN | c.789C>T p.N263= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs372765825; called by muse, mutect2, varscan2
- KRTAP5-7 | c.81C>T p.G27= | Silent (SNP) | VAF 106/392 reads (27%) | called by muse, mutect2, varscan2
- LCT | c.681G>A p.P227= | Silent (SNP) | VAF 127/468 reads (27%) | catalogued as rs954087452, COSV99930519; called by muse, mutect2, varscan2
- LONRF3 | c.360G>A p.A120= | Silent (SNP) | VAF 97/321 reads (30%) | called by muse, mutect2, varscan2
- LRCH2 | c.126C>T p.G42= | Silent (SNP) | VAF 50/184 reads (27%) | called by muse, varscan2
- MANEAL | c.18C>G p.R6= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- MAP3K6 | c.1293C>T p.C431= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs775463638, COSV62888682, COSV62888787; called by muse, mutect2, varscan2
- MOGAT2 | c.601C>T p.L201= | Silent (SNP) | VAF 50/202 reads (25%) | called by muse, mutect2, varscan2
- MSANTD1 | c.423C>T p.G141= | Silent (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- MYBPC2 | c.1380C>T p.C460= | Silent (SNP) | VAF 67/249 reads (27%) | catalogued as rs373913738; called by muse, mutect2, varscan2
- MYO1B | c.3237C>T p.R1079= (on ENST00000304164; = p.R1021= on NM_012223.5) | Silent (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- MYO9A | c.2013T>C p.H671= | Silent (SNP) | VAF 50/166 reads (30%) | called by muse, varscan2
- NALCN | c.2742T>C p.H914= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as rs977844479; called by muse, mutect2, varscan2
- NKX1-1 | c.330G>A p.A110= | Silent (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- NLK | c.210G>A p.S70= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs762851410; called by muse, mutect2, varscan2
- NR3C2 | c.477G>A p.T159= | Silent (SNP) | VAF 65/231 reads (28%) | called by muse, mutect2, varscan2
- OR2W3 | c.726C>G p.G242= | Silent (SNP) | VAF 86/252 reads (34%) | called by muse, mutect2, varscan2
- OR4C15 | c.921C>T p.C307= (on ENST00000314644; = p.C253= on NM_001001920.2) | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV58955976; called by muse, mutect2, varscan2
- OR51M1 | c.471C>T p.G157= | Silent (SNP) | VAF 50/192 reads (26%) | catalogued as COSV60783928; called by muse, mutect2, varscan2
- PBX3 | c.81G>A p.L27= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs897889456; called by muse, mutect2, varscan2
- PCDHA12 | c.1974G>A p.A658= | Silent (SNP) | VAF 99/357 reads (28%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1779C>T p.D593= | Silent (SNP) | VAF 146/800 reads (18%) | catalogued as COSV99178847; called by muse, varscan2
- PCDHGB2 | c.2331G>A p.A777= | Silent (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- PDCD10 | c.384G>A p.L128= | Silent (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- PDK3 | c.117T>C p.N39= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2
- PKD1L2 | c.1242C>A p.T414= | Silent (SNP) | VAF 16/305 reads (5%) | called by muse, mutect2
- PKHD1 | c.2025G>A p.Q675= | Silent (SNP) | VAF 90/281 reads (32%) | called by muse, mutect2, varscan2
- PLEC | c.10167G>T p.T3389= (on ENST00000322810 / NM_201380.4; = p.T3279= on NM_000445.5) | Silent (SNP) | VAF 163/585 reads (28%) | catalogued as COSV59604436; called by muse, mutect2, varscan2
- PLIN4 | c.1518C>T p.G506= (on ENST00000301286; = p.G521= on NM_001367868.2) | Silent (SNP) | VAF 162/574 reads (28%) | catalogued as rs754429889; called by mutect2, varscan2
- POLG | c.459G>A p.A153= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- PRKN | c.300G>A p.Q100= | Silent (SNP) | VAF 175/525 reads (33%) | catalogued as COSV58259214, COSV58291662; called by muse, varscan2
- PRPF8 | c.6168C>A p.T2056= | Silent (SNP) | VAF 195/619 reads (32%) | called by muse, mutect2, varscan2
- R3HDM4 | c.97C>T p.L33= | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as rs1173061584; called by muse, mutect2, varscan2
- RAPGEF1 | c.921C>T p.S307= | Silent (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- RBM33 | c.3294C>T p.C1098= | Silent (SNP) | VAF 57/236 reads (24%) | catalogued as rs1211615158, COSV62031415; called by muse, mutect2, varscan2
- RGPD8 | c.3555C>T p.G1185= | Silent (SNP) | VAF 68/183 reads (37%) | catalogued as rs1207575418; called by mutect2, varscan2
- RPS6KA4 | c.1458G>A p.L486= | Silent (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
- RXRA | c.723C>T p.A241= | Silent (SNP) | VAF 67/234 reads (29%) | catalogued as rs374685246; called by muse, mutect2, varscan2
- SALL2 | c.2913C>A p.P971= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs920854509; called by muse, mutect2, varscan2
- SCRT2 | c.309C>T p.T103= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs757031485; called by muse, mutect2, varscan2
- SEL1L3 | c.2994G>A p.T998= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs775288846; called by muse, mutect2, varscan2
- SEMA4D | c.1956C>T p.P652= | Silent (SNP) | VAF 53/181 reads (29%) | catalogued as rs781459597; called by muse, mutect2, varscan2
- SHH | c.1363C>T p.L455= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1315242350; called by muse, varscan2
- SIK2 | c.1506C>T p.F502= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, varscan2
- SIPA1L3 | c.759C>G p.G253= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs1169786424, COSV55912715, COSV55918017; called by muse, mutect2, varscan2
- SKIDA1 | c.705C>T p.A235= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs541879371; called by muse, varscan2
- SLC41A3 | c.1200A>G p.S400= | Silent (SNP) | VAF 41/196 reads (21%) | called by muse, mutect2, varscan2
- SNX22 | c.180G>A p.V60= | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as rs775189306; called by muse, mutect2, varscan2
- SORCS2 | c.3342A>G p.Q1114= | Silent (SNP) | VAF 62/206 reads (30%) | called by muse, varscan2
- SOS2 | c.3531G>A p.P1177= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1248324702; called by muse, mutect2, varscan2
- SPECC1L | c.2439C>T p.A813= | Silent (SNP) | VAF 98/334 reads (29%) | catalogued as rs182111653, COSV100062993; called by muse, mutect2, varscan2
- STAC3 | c.546C>T p.R182= | Silent (SNP) | VAF 85/305 reads (28%) | catalogued as COSV100234539; called by muse, mutect2, varscan2
- TBX4 | c.346C>T p.L116= | Silent (SNP) | VAF 135/471 reads (29%) | catalogued as rs1159101510; called by muse, mutect2, varscan2
- TFPT | c.216G>C p.R72= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as COSV58085907; called by muse, mutect2, varscan2
- TLR9 | c.2922C>T p.D974= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs200718751, COSV62345637; called by muse, mutect2, varscan2
- TMEM120A | c.399T>C p.Y133= | Silent (SNP) | VAF 79/286 reads (28%) | called by muse, mutect2, varscan2
- TMEM8B | c.918G>A p.V306= | Silent (SNP) | VAF 52/232 reads (22%) | catalogued as rs1347532925; called by muse, mutect2, varscan2
- TRIM54 | c.240G>A p.S80= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs540676343, COSV56081948; called by muse, mutect2
- TRIM71 | c.2136C>T p.G712= | Silent (SNP) | VAF 83/261 reads (32%) | catalogued as COSV67470239; called by muse, mutect2, varscan2
- UBE2J1 | c.666G>A p.T222= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs375378658; called by muse, mutect2, varscan2
- ZC3H3 | c.2619C>T p.S873= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs17853854; called by muse, varscan2
- ZFP92 | c.327C>T p.P109= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs950906389; called by muse, mutect2
- ZNF605 | c.639G>T p.T213= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- AC002511.3 | n.325-72G>A | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084395 C>T | 5'Flank (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- ACADS | c.473-39G>T | Intron (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- ACTG1 | c.*595dup | 3'UTR (INS) | VAF 22/86 reads (26%) | catalogued as rs550314896; called by mutect2, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 14/72 reads (19%) | catalogued as rs779843196; called by pindel, varscan2*
- ADGRB2 | c.3353+12dup | Intron (INS) | VAF 37/150 reads (25%) | catalogued as rs759961385; called by mutect2, varscan2
- AF186192.2 | n.85del | RNA (DEL) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- AJAP1 | c.-55C>T | 5'UTR (SNP) | VAF 54/198 reads (27%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840236 G>A | 5'Flank (SNP) | VAF 128/481 reads (27%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822434 del T | 5'Flank (DEL) | VAF 89/289 reads (31%) | called by mutect2, pindel, varscan2
- ALPL | c.-50G>A | 5'UTR (SNP) | VAF 78/225 reads (35%) | catalogued as rs756589854, COSV100876912; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1029del | RNA (DEL) | VAF 6/24 reads (25%) | catalogued as rs541299432; called by mutect2, varscan2
- AP2A2 | c.*739C>T | 3'UTR (SNP) | VAF 52/156 reads (33%) | catalogued as rs550046412; called by muse, mutect2, varscan2
- APAF1 | c.*54del | 3'UTR (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- ARMCX4 | c.1038+3777C>T | Intron (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- ARPP21 | c.898-10del | Intron (DEL) | VAF 34/94 reads (36%) | catalogued as rs751740483; called by mutect2, varscan2
- ASL | c.656-3del | Intron (DEL) | VAF 181/653 reads (28%) | catalogued as rs778811159; called by mutect2, pindel, varscan2
- B3GNT4 | c.*822C>A | 3'UTR (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- BCAP29 | c.345-6del | Intron (DEL) | VAF 31/105 reads (30%) | called by mutect2, varscan2
- BEAN1 | chr16:66484806 C>T | 3'Flank (SNP) | VAF 135/485 reads (28%) | catalogued as rs1292560802; called by muse, mutect2, varscan2
- BRCA1 | c.-20+107del | Intron (DEL) | VAF 67/214 reads (31%) | called by mutect2, pindel, varscan2
- CA2 | c.-47_-45dup | 5'UTR (INS) | VAF 141/617 reads (23%) | catalogued as rs1367491569; called by mutect2, varscan2
- CFL2 | c.*964del | 3'UTR (DEL) | VAF 25/80 reads (31%) | catalogued as rs758463033; called by mutect2, varscan2
- COL27A1 | c.4639-75A>C | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- DAPK3 | c.630-307del | Intron (DEL) | VAF 96/295 reads (33%) | called by mutect2, pindel, varscan2
- DCAF17 | c.*188del | 3'UTR (DEL) | VAF 42/124 reads (34%) | catalogued as rs746203651; called by mutect2, varscan2
- DDX41 | c.*548C>T | 3'UTR (SNP) | VAF 59/192 reads (31%) | called by muse, mutect2, varscan2
- DENND4C | c.5676-59dup | Intron (INS) | VAF 14/54 reads (26%) | catalogued as rs908487986; called by mutect2, varscan2
- DEPDC7 | c.73+521T>C | Intron (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- DMTN | c.*855del | 3'UTR (DEL) | VAF 7/50 reads (14%) | catalogued as rs1300307029; called by mutect2, pindel, varscan2
- DNM1P47 | n.655C>T | RNA (SNP) | VAF 81/339 reads (24%) | catalogued as rs139649266; called by muse, mutect2, varscan2
- DOCK8 | c.53+14del | Intron (DEL) | VAF 42/152 reads (28%) | catalogued as rs749863710; called by mutect2, pindel, varscan2
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 38/118 reads (32%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- FAM183BP | n.815A>G | RNA (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662768 del C | 5'Flank (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- GHSR | c.796+17_796+18del | Intron (DEL) | VAF 27/88 reads (31%) | called by pindel, varscan2
- GK | c.-18C>T | 5'UTR (SNP) | VAF 195/856 reads (23%) | catalogued as rs370271242; called by muse, mutect2, varscan2
- H2AZ1 | c.82-129dup | Intron (INS) | VAF 68/263 reads (26%) | catalogued as rs751578214; called by mutect2, varscan2
- HERC2P3 | n.398G>A | RNA (SNP) | VAF 112/592 reads (19%) | catalogued as rs567212534; called by muse, mutect2, varscan2
- HSD11B1L | c.669-27C>T | Intron (SNP) | VAF 53/237 reads (22%) | catalogued as rs1360141750; called by muse, mutect2, varscan2
- ITGA9 | c.2890-12G>A | Intron (SNP) | VAF 129/497 reads (26%) | catalogued as rs373646093; called by muse, mutect2, varscan2
- KLC2 | c.1785+45del | Intron (DEL) | VAF 74/223 reads (33%) | called by mutect2, pindel, varscan2
- KLF6 | c.*914del | 3'UTR (DEL) | VAF 8/25 reads (32%) | catalogued as rs891275616; called by mutect2, varscan2
- L3MBTL3 | c.215-66del | Intron (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel
- LINC00174 | n.3603C>T | RNA (SNP) | VAF 34/110 reads (31%) | catalogued as rs753238951; called by muse, mutect2
- LINC02054 | n.2595-11572del | Intron (DEL) | VAF 59/193 reads (31%) | called by mutect2, varscan2
- LLGL2 | c.1036+24G>A | Intron (SNP) | VAF 19/69 reads (28%) | catalogued as rs373341692; called by muse, mutect2
- LY6G5C | c.346-1084G>A | Intron (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2
- MACF1 | c.543+11439G>A | Intron (SNP) | VAF 76/259 reads (29%) | catalogued as rs1342541245; called by muse, mutect2, varscan2
- MAD1L1 | c.1417-198del | Intron (DEL) | VAF 62/177 reads (35%) | called by mutect2, pindel, varscan2
- MAZ | c.1280-385del | Intron (DEL) | VAF 7/26 reads (27%) | catalogued as rs769505112; called by mutect2, varscan2
- MCU | c.496+1222A>G | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as rs1388980191; called by muse, mutect2, varscan2
- MECP2 | c.-165G>A | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100318028; called by muse, mutect2
- MED13L | c.2570-24A>T | Intron (SNP) | VAF 41/117 reads (35%) | catalogued as rs766244256; called by muse, mutect2, varscan2
- MSTO1 | c.367-61G>A | Intron (SNP) | VAF 52/208 reads (25%) | catalogued as rs760942243; called by muse, mutect2, varscan2
- MYO1F | c.414+45G>A | Intron (SNP) | VAF 143/444 reads (32%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.*449del | 3'UTR (DEL) | VAF 52/168 reads (31%) | catalogued as rs780771335; called by mutect2, varscan2
- NEU4 | c.-192G>T | 5'UTR (SNP) | VAF 30/103 reads (29%) | catalogued as COSV57991648; called by muse, mutect2, varscan2
- NPHS2 | c.874-11_874-10del | Intron (DEL) | VAF 34/152 reads (22%) | catalogued as rs774075788; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NRP1 | c.1614+169C>T | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- NXF5 | n.1563C>G | RNA (SNP) | VAF 78/267 reads (29%) | catalogued as rs774498594; called by muse, mutect2, varscan2
- OR51A4 | chr11:4943487 del T | 3'Flank (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- PALLD | c.1965-12692A>G | Intron (SNP) | VAF 98/423 reads (23%) | called by muse, mutect2, varscan2
- PARP1 | c.834+51G>A | Intron (SNP) | VAF 52/222 reads (23%) | catalogued as rs573931255; called by muse, mutect2, varscan2
- PCDHA13 | c.*239G>A | 3'UTR (SNP) | VAF 47/175 reads (27%) | catalogued as COSV99144056; called by muse, mutect2, varscan2
- PGGHG | c.1271-71G>A | Intron (SNP) | VAF 96/228 reads (42%) | catalogued as rs749593314; called by muse, mutect2, varscan2
- PIGA | c.-63+96del | Intron (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- PLEKHH2 | c.186+665G>A | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PRRT1 | c.-45C>A | 5'UTR (SNP) | VAF 64/262 reads (24%) | called by muse, mutect2, varscan2
- PRRT1 | c.-46A>G | 5'UTR (SNP) | VAF 62/255 reads (24%) | called by muse, mutect2, varscan2
- QKI | c.935-47del | Intron (DEL) | VAF 34/174 reads (20%) | catalogued as COSV99274476; called by pindel, varscan2
- QSER1 | c.5067+29del | Intron (DEL) | VAF 35/106 reads (33%) | catalogued as rs747734792; called by mutect2, varscan2
- RAD51D | c.-22del | 5'UTR (DEL) | VAF 216/756 reads (29%) | called by mutect2, pindel, varscan2
- RPGR | c.2520+327C>T | Intron (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- RPL24 | c.393+58del | Intron (DEL) | VAF 26/83 reads (31%) | catalogued as rs1559992537; called by mutect2, pindel, varscan2
- SCARB2 | chr4:76217664 A>G | 5'Flank (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- SCLT1 | c.235-1110C>T | Intron (SNP) | VAF 18/108 reads (17%) | catalogued as rs1013184751; called by muse, mutect2, varscan2
- SH3TC2 | c.280-1326del | Intron (DEL) | VAF 16/54 reads (30%) | catalogued as rs752479043; called by mutect2, varscan2
- SLC22A20P | n.613G>A | RNA (SNP) | VAF 48/189 reads (25%) | catalogued as rs201053912; called by muse, mutect2, varscan2
- SLC39A4 | c.-14G>A | 5'UTR (SNP) | VAF 107/396 reads (27%) | catalogued as rs782109010; called by muse, mutect2, varscan2
- SMPD4 | c.1215-73G>A | Intron (SNP) | VAF 77/271 reads (28%) | called by muse, mutect2, varscan2
- SMS | c.-24C>T | 5'UTR (SNP) | VAF 184/529 reads (35%) | called by muse, mutect2, varscan2
- SPTLC3 | c.1546-394A>G | Intron (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- SRSF11 | c.338-1676del | Intron (DEL) | VAF 26/116 reads (22%) | catalogued as rs546561685; called by mutect2, varscan2
- SSPOP | n.6641C>T | RNA (SNP) | VAF 34/143 reads (24%) | catalogued as rs779442919; called by muse, mutect2, varscan2
- STAB1 | c.4762-10G>A | Intron (SNP) | VAF 44/163 reads (27%) | catalogued as rs1559711774; called by muse, mutect2, varscan2
- TCEAL4 | c.-22-429G>A | Intron (SNP) | VAF 37/137 reads (27%) | catalogued as rs1031107522; called by muse, mutect2, varscan2
- TRAK1 | c.1744+36C>A | Intron (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- TSPAN32 | c.628-103C>T | Intron (SNP) | VAF 56/229 reads (24%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1103G>A | Intron (SNP) | VAF 91/290 reads (31%) | called by muse, mutect2, varscan2
- WDR55 | c.-7_-5del | 5'UTR (DEL) | VAF 28/144 reads (19%) | catalogued as rs769958588; called by mutect2, pindel, varscan2
